Somatic mutation profile of tumor specimen MBCProject_0226_T2_WES (aliquot MBCProject_0226_T2_WES_1) from CMI case MBCProject_0226, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 38.6 years (14,091 days).
Specimen MBCProject_0226_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ccd2f24-4dc9-4d34-bbf2-861472046a2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0226_SALIVA (Saliva), aliquot MBCProject_0226_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d8a0219-92b4-4a8a-89d0-4267b9b2b738

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Nonsense Mutation 3, 5'Flank 2, Intron 1, Splice Region 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100711718; called by muse, mutect2, varscan2
- ARMC9 | c.2119G>A p.V707I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs892448059; called by muse, mutect2, varscan2
- CMYA5 | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs1457682264; called by muse, varscan2
- CRIP3 | c.42C>T p.F14= | Splice Region (SNP) | VAF 23/160 reads (14%) | catalogued as COSV51484513; called by muse, mutect2, varscan2
- LGALS12 | c.662T>C p.L221P | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99737271; called by muse, mutect2, varscan2
- MUC3A | c.7235C>T p.S2412L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated, low confidence (0.08); catalogued as rs756681666; called by muse, mutect2, varscan2
- PDK2 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368388043; called by muse, varscan2
- PKD1 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 18/335 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774610211; called by muse, mutect2
- PRKCG | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1313302986; called by muse, mutect2, varscan2
- RSPO4 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs762295741, COSV99449150; called by muse, mutect2, varscan2
- SCAF1 | c.3203C>T p.S1068L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs763275837; called by muse, mutect2, varscan2
- SPTLC1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.32); catalogued as rs745684683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF420 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV100421397; called by muse, varscan2
- ABCD2 | c.65G>T p.R22M | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2
- CDH1 | c.873del p.D291Efs*3 | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | called by mutect2, pindel, varscan2
- CST2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IL17F | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRS4 | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MAP2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NHLRC1 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFKL | c.1665C>G p.I555M | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIWIL1 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- PLEKHD1 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 71/262 reads (27%) | called by muse, mutect2, varscan2
- PRR12 | c.772C>T p.H258Y (on ENST00000615927; = p.H1079Y on NM_020719.3) | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RNPEPL1 | c.601T>C p.C201R | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERPINE2 | c.840G>A p.W280* | Nonsense Mutation (SNP) | VAF 48/230 reads (21%) | called by muse, mutect2, varscan2
- TLR8 | c.2806A>T p.I936F (on ENST00000218032 / NM_138636.5; = p.I954F on NM_016610.4) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- UHRF2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UNC13A | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.035); called by muse, varscan2
- ZNF420 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- ZYX | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB8 | c.915G>C p.L305= (on ENST00000297504 / NM_001282291.2; = p.L288= on NM_007188.5) | Silent (SNP) | VAF 49/182 reads (27%) | called by muse, mutect2, varscan2
- GTF3C1 | c.4650C>T p.N1550= | Silent (SNP) | VAF 72/493 reads (15%) | catalogued as rs373643267; called by muse, mutect2, varscan2
- MAGEL2 | c.735G>A p.P245= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1042816043; called by muse, mutect2, varscan2
- NID1 | c.2571C>T p.L857= | Silent (SNP) | VAF 61/204 reads (30%) | catalogued as rs145436948; called by muse, mutect2, varscan2
- PCDHA9 | c.1797C>T p.A599= | Silent (SNP) | VAF 95/382 reads (25%) | catalogued as rs782042640, COSV65331899; called by muse, mutect2, varscan2
- RAB10 | c.30C>T p.F10= | Silent (SNP) | VAF 39/205 reads (19%) | catalogued as COSV53088048; called by muse, mutect2, varscan2
- RFX6 | c.1530C>T p.L510= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as rs765608557; called by muse, mutect2, varscan2
- SIDT1 | c.2272C>T p.L758= | Silent (SNP) | VAF 61/242 reads (25%) | catalogued as COSV99333123; called by muse, mutect2, varscan2
- SYNJ2 | c.2961C>T p.P987= | Silent (SNP) | VAF 55/241 reads (23%) | catalogued as rs904416986; called by muse, mutect2, varscan2
- ZNF420 | c.1434G>A p.K478= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1395373327; called by muse, mutect2, varscan2
- CHN1 | c.550-162G>A | Intron (SNP) | VAF 10/39 reads (26%) | called by muse, varscan2
- SOX5 | chr12:23950882 C>T | 5'Flank (SNP) | VAF 26/136 reads (19%) | called by muse, varscan2
- SYCE1 | chr10:133568222 C>T | 5'Flank (SNP) | VAF 38/167 reads (23%) | catalogued as rs1329214679; called by muse, mutect2, varscan2
- XIAP | c.*3773A>G | 3'UTR (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
